Somatic mutation profile of tumor specimen TARGET-30-PAUGZD-01A (aliquot TARGET-30-PAUGZD-01A-01D) from TARGET case TARGET-30-PAUGZD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.5 years (2,016 days).
Specimen TARGET-30-PAUGZD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67b9503b-d4f5-4822-97d9-7c05189df014.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUGZD-10A (Blood Derived Normal), aliquot TARGET-30-PAUGZD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cbface9-d3d4-4c2d-a2ed-44ab1125dd79

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 102/151 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH2 | c.3465C>A p.D1155E | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1290118226, COSV66720618; called by muse, mutect2, varscan2
- ATRX | c.1983_1986dup p.P663Yfs*10 | Frame Shift Ins (INS) | VAF 61/74 reads (82%) | called by mutect2, pindel, varscan2
